TCGA case TCGA-CV-6948 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fcf0dc48-b889-4593-a15b-aa715aae7bf5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 79 years; Vital status: Dead; Days to death: 1,289 days (3.5 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C04.9; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 79.8 years (29,153 days); Year of diagnosis: 1994; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N3; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,289 days (3.5 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 30; Lymph nodes tested: 44; Margin status: Uninvolved.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 1,289 days (3.5 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CV-6948-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.5; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-CV-6948-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-CV-6948-01A-01-BS1: Section location: Bottom; Percent tumor cells: 99; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
- Sample TCGA-CV-6948-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CV-6948-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymph node neck dissection indicator: Yes; Margin status: Negative; Alcohol history documented: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,289 days; disease-specific survival: no event (censored), 1,289 days; progression-free interval: no event (censored), 1,289 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CV-6948-01A-11D-1910-01): tumor purity 0.84, ploidy 1.84, whole-genome doublings 0.
